Somatic mutation profile of tumor specimen TCGA-SQ-A6I4-01A (aliquot TCGA-SQ-A6I4-01A-11D-A35I-08) from TCGA case TCGA-SQ-A6I4, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 53.1 years (19,399 days).
Specimen TCGA-SQ-A6I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e350ae57-b024-4b0a-8868-96f984d0999e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SQ-A6I4-10A (Blood Derived Normal), aliquot TCGA-SQ-A6I4-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66df8fc6-a824-41ed-950e-be3e52d6bc89

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGEL1 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99200428; called by muse, mutect2, varscan2
- MAP2K1 | c.159_173del p.F53_Q58delinsL | In Frame Del (DEL) | VAF 22/120 reads (18%) | catalogued as COSV61072289; called by mutect2, pindel, varscan2
- SOCS5 | c.1247C>A p.S416Y | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60604932; called by muse, mutect2, varscan2
- PML | c.2015C>G p.P672R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
